Gene-level copy-number profile of tumor specimen TCGA-D7-A4YX-01A from TCGA case TCGA-D7-A4YX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 63.7 years (23,249 days).
Specimen TCGA-D7-A4YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e82cfaa1-3baa-4cf3-a155-06366df63c8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A4YX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2b1a68e-4b15-4d16-abc8-ea122f8e21fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,190; copy number 2: 50,280; copy number 3: 6,290; copy number 19: 6; copy number 23: 40; copy number 29: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A4YX-01A-11D-A253-01): tumor purity 0.55, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr20:14,757,563–14,758,056, 1 gene: RPS10P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:41,162,287–41,260,096, 3 genes, copy number 29: AC009743.1, MRPS31P1, CTNNB1.
- chr17:39,671,122–39,864,312, 6 genes, copy number 19 (within-gene range 2–19): PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:39,980,807–40,115,442, 9 genes, copy number 23 (within-gene range 2–23): PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1.
- chr17:41,148,924–41,454,055, 31 genes, copy number 23 (within-gene range 2–23): KRTAP4-5, KRTAP4-4, KRTAP4-3, KRTAP4-2, KRTAP4-1, KRTAP4-17P, KRTAP9-1, KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P.

Autosomal genes at a single copy (total copy number 1): 1,285. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
